Somatic mutation profile of tumor specimen TCGA-AJ-A2QN-01A (aliquot TCGA-AJ-A2QN-01A-11D-A18P-09) from TCGA case TCGA-AJ-A2QN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.0 years (21,915 days).
Specimen TCGA-AJ-A2QN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b2860ee-dd09-404b-9de9-3d6b62f3da36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A2QN-10A (Blood Derived Normal), aliquot TCGA-AJ-A2QN-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eec50ad-8a87-479e-a531-2c28b1051967

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 2, Splice Site 2, In Frame Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSA | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315460, CM940097, COSV99332252; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 34/87 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.634+2_634+11del p.X212_splice | Splice Site (DEL) | VAF 6/16 reads (38%) | hotspot (GDC flag); called by mutect2, varscan2
- AFF2 | c.1785A>T p.K595N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV53987304, COSV99661569; called by muse, mutect2, varscan2
- ASB16 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as rs1293724098, COSV99518722; called by muse, mutect2, varscan2
- ATP8B4 | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs114013910, COSV99463198; called by muse, mutect2, varscan2
- BCL11A | c.749C>T p.A250V (on ENST00000335712 / NM_001365609.1; = p.A284V on NM_018014.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100184651; called by muse, mutect2, varscan2
- C11orf53 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV99724595; called by mutect2, varscan2
- CERS2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs751123315, COSV54995569; called by muse, mutect2
- CNKSR1 | c.1850A>G p.N617S (on ENST00000374253 / NM_001297647.2; = p.N610S on NM_006314.3) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100128175; called by muse, mutect2
- CNPPD1 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs768238546, COSV55407680; called by muse, mutect2, varscan2
- CRYGB | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1461895852, COSV53680151; called by muse, mutect2
- EIF2AK3 | c.2909C>T p.T970M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs751166753, COSV57544965; called by muse, mutect2, varscan2
- GARS1 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as rs1406586832, COSV101219887; called by muse, mutect2, varscan2
- GPKOW | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99332455; called by muse, mutect2, varscan2
- GTF3C5 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443675764, COSV59601696; called by muse, mutect2, varscan2
- KLK15 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs112887731, COSV56827138; called by muse, mutect2, varscan2
- KLRC3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs768046359, COSV101122914, COSV67251385; called by muse, mutect2, varscan2
- LEFTY1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs150915411; called by muse, mutect2, varscan2
- LOXL1 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99985152; called by muse, mutect2, varscan2
- MAML2 | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV101593936; called by muse, mutect2, varscan2
- MED12 | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 38/62 reads (61%) | catalogued as COSV61359729; called by muse, mutect2, varscan2
- MLLT1 | c.345C>G p.N115K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53131291; called by muse, mutect2, varscan2
- PCDHA13 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56515710; called by muse, mutect2, varscan2
- PCDHA2 | c.1549G>C p.V517L | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV100973477, COSV100973987; called by muse, mutect2, varscan2
- PCLO | c.13012A>T p.K4338* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100426754; called by muse, mutect2, varscan2
- PPM1B | c.914C>G p.A305G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as COSV99175675; called by muse, mutect2, varscan2
- PPP2R2B | c.910G>A p.V304I (on ENST00000394409; = p.V370I on NM_181674.2) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs369931023; called by muse, mutect2, varscan2
- PRSS36 | c.2136G>A p.W712* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99191221; called by muse, mutect2, varscan2
- PYCR2 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.188); catalogued as COSV100661466; called by muse, mutect2, varscan2
- RMDN3 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs144235442; called by muse, mutect2, varscan2
- RRP12 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs769264384, COSV100212844; called by muse, mutect2, varscan2
- SFPQ | c.1328G>C p.R443P | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100599256, COSV61758573; called by muse, mutect2, varscan2
- SKI | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as rs771845588, COSV101049186; called by muse, varscan2
- SLC4A1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371106409; called by muse, mutect2, varscan2
- SORBS1 | c.2767G>A p.V923M (on ENST00000361941 / NM_001034954.2; = p.V573M on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867269550, COSV53352827; called by muse, mutect2, varscan2
- SORCS2 | c.1649G>T p.C550F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100211269, COSV61165584; called by muse, mutect2, varscan2
- TMEM175 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs140775030; called by muse, mutect2, varscan2
- TRPC4 | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV100155714; called by muse, mutect2, varscan2
- TTLL1 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs147239263, COSV99840106; called by muse, mutect2, varscan2
- VCL | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV99280364; called by muse, mutect2, varscan2
- WIZ | c.2627G>A p.R876Q (on ENST00000673675 / NM_001371589.1; = p.R139Q on NM_021241.3) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs376481490; called by muse, mutect2, varscan2
- ZSCAN2 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs140001287; called by muse, mutect2, varscan2
- PIK3R1 | c.1670_1681dup p.R557_D560dup (on ENST00000521381 / NM_181523.3; = p.R287_D290dup on NM_181504.4) | In Frame Ins (INS) | VAF 11/35 reads (31%) | called by mutect2, varscan2
- TMEM236 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX37 | c.561G>A p.P187= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs772227260, COSV100438916; called by muse, mutect2, varscan2
- IGKV1-17 | c.210C>A p.I70= | Silent (SNP) | VAF 38/75 reads (51%) | called by muse, varscan2
- ITGA4 | c.912G>A p.S304= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs369818648; called by muse, mutect2, varscan2
- KCNA5 | c.207G>A p.P69= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99363562; called by muse, varscan2
- MAP3K1 | c.744A>T p.R248= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101266103; called by muse, mutect2, varscan2
- MUC5AC | c.14901C>T p.C4967= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs188152234, COSV100611295; called by muse, mutect2, varscan2
- PCDHB12 | c.1875C>A p.R625= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV99506604; called by muse, varscan2
- PCDHB2 | c.1680G>A p.S560= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as COSV99164122; called by muse, mutect2, varscan2
- PHACTR1 | c.672C>T p.G224= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs540161880, COSV60674744; called by muse, mutect2, varscan2
- PIGG | c.2346C>T p.V782= (on ENST00000453061 / NM_001127178.3; = p.V774= on NM_017733.4) | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99573536; called by muse, mutect2, varscan2
- PLEC | c.2145C>T p.D715= (on ENST00000322810 / NM_201380.4; = p.D605= on NM_000445.5) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs782141897, COSV100509762; called by muse, mutect2, varscan2
- TCF21 | c.372G>A p.A124= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs201214778, COSV99399490; called by muse, mutect2, varscan2
- THOC2 | c.1818A>G p.S606= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV99832647; called by muse, mutect2, varscan2
- ZFR2 | c.1341G>A p.A447= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs371065673, COSV53599890; called by muse, mutect2, varscan2
- RNF217-AS1 | n.293T>C | RNA (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149777681 G>A | 5'Flank (SNP) | VAF 39/76 reads (51%) | catalogued as rs374482349; called by muse, mutect2, varscan2
